Somatic mutation profile of tumor specimen MP2PRT-PATLGS-TMP1-A (aliquot MP2PRT-PATLGS-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATLGS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,207 days).
Specimen MP2PRT-PATLGS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4922f28-01bd-4cdb-8c3e-ec6c34b06da8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATLGS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATLGS-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f626bc9-5232-4666-a75f-cf8a5ce8b95b

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, 5'UTR 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 167/400 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs192838388, CM034722; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCOR | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 182/333 reads (55%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1180666937, COSV100654036; called by muse, varscan2
- CAPN14 | c.1578C>A p.F526L | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV67289985; called by muse, mutect2
- LEPR | c.2794G>C p.D932H | Missense Mutation (SNP) | VAF 112/253 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs775396567; called by muse, mutect2, varscan2
- NAGPA | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 185/402 reads (46%) | PolyPhen probably damaging (0.999); catalogued as rs142777588; called by muse, mutect2, varscan2
- RFX8 | c.1390C>T p.P464S (on ENST00000646446; = p.P393S on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/428 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs746230392; called by muse, mutect2, varscan2
- ZNF236 | c.978G>A p.T326= | Splice Region (SNP) | VAF 49/206 reads (24%) | catalogued as rs1230729714, COSV99471676; called by muse, mutect2, varscan2
- BAHD1 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 232/518 reads (45%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406870 ATTCACA>GGGC | Missense Mutation (DEL) | VAF 82/202 reads (41%) | called by pindel, varscan2*
- NFRKB | c.374A>C p.Q125P (on ENST00000446488 / NM_001143835.2; = p.Q138P on NM_006165.3) | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- PKD1L1 | c.3632T>C p.V1211A | Missense Mutation (SNP) | VAF 161/369 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- RNF43 | c.1967G>A p.R656K | Missense Mutation (SNP) | VAF 30/548 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.079); called by muse, mutect2
- ZFPM1 | c.405C>G p.S135R | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.216); called by mutect2, varscan2
- PTK2B | c.159G>A p.G53= | Silent (SNP) | VAF 108/297 reads (36%) | catalogued as COSV100593747; called by muse, mutect2, varscan2
- SPEM3 | c.1800C>T p.L600= | Silent (SNP) | VAF 18/446 reads (4%) | called by muse, mutect2
- TRIM41 | c.-211C>T | 5'UTR (SNP) | VAF 154/350 reads (44%) | called by muse, mutect2, varscan2
